Somatic mutation profile of tumor specimen TCGA-AG-3885-01A (aliquot TCGA-AG-3885-01A-01W-0899-10) from TCGA case TCGA-AG-3885, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 71.6 years (26,145 days).
Specimen TCGA-AG-3885-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08b03167-09ef-4b8c-b655-37ddb7bea589.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3885-10A (Blood Derived Normal), aliquot TCGA-AG-3885-10A-01W-0901-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20a6144b-ac74-4b9b-bcf3-58c99a12c322

The open-access MAF lists 99 somatic variants for this specimen: 77 protein-altering or splice-affecting, 18 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 18, Nonsense Mutation 4, Frame Shift Del 4, Frame Shift Ins 2, Splice Site 2, Intron 2, In Frame Del 1, 5'UTR 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4188dup p.E1397* | Frame Shift Ins (INS) | VAF 124/296 reads (42%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ATM | c.6115G>A p.E2039K | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs864622251, CM094668, COSV53740536, COSV53772321; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- COL6A1 | c.1603G>A p.G535R | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764556767, COSV100720032; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KRAS | c.351A>T p.K117N | Missense Mutation (SNP) | VAF 246/310 reads (79%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770248150, COSV55504752, COSV55545304; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 62/83 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1131691025, COSV52677105, COSV52952688; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTN2 | c.2377G>A p.E793K | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs145450474, COSV63977118; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AK5 | c.227G>A p.R76Q (on ENST00000354567 / NM_174858.3; = p.R50Q on NM_012093.4) | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.859); catalogued as rs751153431, COSV58355247; called by muse, mutect2, varscan2
- ANK2 | c.344T>G p.V115G | Missense Mutation (SNP) | VAF 90/368 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100000435; called by mutect2, varscan2
- APC | c.3077del p.N1026Ifs*11 | Frame Shift Del (DEL) | VAF 36/106 reads (34%) | catalogued as COSV57370940; called by mutect2, pindel, varscan2
- ARHGAP21 | c.1030A>G p.I344V | Missense Mutation (SNP) | VAF 238/467 reads (51%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as COSV100255940; called by muse, mutect2, varscan2
- ATM | c.5044G>T p.D1682Y | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as CM0910509, COSV53728454, COSV53735978; called by muse, mutect2, varscan2
- ATP9B | c.1462G>A p.V488M | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.947); catalogued as rs201117656, COSV100303117; called by muse, mutect2, varscan2
- BCL9L | c.1876del p.M626* | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | catalogued as COSV52681903; called by mutect2, varscan2
- CASP5 | c.1076C>A p.A359D | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99507337; called by muse, mutect2, varscan2
- CATSPER2 | c.319+2T>C p.X107_splice | Splice Site (SNP) | VAF 3/48 reads (6%) | catalogued as COSV100390627; called by muse, mutect2
- CCDC171 | c.3453A>C p.E1151D | Missense Mutation (SNP) | VAF 162/296 reads (55%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.654); catalogued as COSV99900091; called by muse, mutect2, varscan2
- CH25H | c.411G>A p.M137I | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100897334; called by muse, mutect2, varscan2
- CHDH | c.1087T>C p.C363R | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100179614; called by mutect2, varscan2
- CLSPN | c.2533G>C p.A845P | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.353); catalogued as COSV52053147, COSV99231203; called by muse, mutect2, varscan2
- CMYA5 | c.6889G>A p.D2297N | Missense Mutation (SNP) | VAF 136/283 reads (48%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as rs377265303; called by muse, mutect2, varscan2
- CPT1A | c.623A>C p.D208A | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); catalogued as COSV99680796; called by muse, mutect2, varscan2
- CXCR4 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.106); catalogued as rs771851938, COSV54018035; called by mutect2, varscan2
- DLGAP5 | c.1486C>T p.R496* | Nonsense Mutation (SNP) | VAF 81/343 reads (24%) | catalogued as rs565083852, COSV55962927; called by muse, varscan2
- EIF2S3 | c.728T>C p.I243T | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.182); catalogued as COSV99450748; called by muse, mutect2, varscan2
- ELF1 | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 220/524 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.079); catalogued as rs750744628, COSV99522904; called by muse, mutect2, varscan2
- FAM47B | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs1181134835, COSV100264635, COSV61457176; called by muse, varscan2
- FARS2 | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145697325, COSV51169101; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FDX2 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.93); PolyPhen benign (0.224); catalogued as rs776983522, COSV100593719; called by muse, mutect2, varscan2
- GABRA1 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs1164973274, COSV50099709, COSV50102525; called by muse, mutect2, varscan2
- GZMA | c.557A>G p.N186S | Missense Mutation (SNP) | VAF 44/215 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as COSV99696654; called by muse, mutect2, varscan2
- HAS1 | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.132); catalogued as rs768198571, COSV99708274; called by muse, mutect2, varscan2
- HSD17B3 | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs377018679; called by muse, mutect2, varscan2
- KAT7 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs1006528415, COSV99371657; called by muse, mutect2, varscan2
- KCNA2 | c.1108G>A p.V370I | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs756214647, COSV60369282; called by muse, mutect2, varscan2
- KIAA1755 | c.2990G>A p.R997H | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as rs747051689, COSV54073295; called by muse, mutect2, varscan2
- LAGE3 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs1557211331, COSV104422189; called by muse, mutect2
- LCE3A | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 65/105 reads (62%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV100175092, COSV59551214; called by muse, mutect2, varscan2
- LMO2 | c.298C>T p.R100W (on ENST00000395833 / NM_001142315.2; = p.R169W on NM_005574.4) | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1565019810, COSV57646288; called by muse, mutect2, varscan2
- MCM9 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.85); catalogued as COSV60164220; called by muse, mutect2, varscan2
- MEPE | c.371A>G p.K124R | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV63073240; called by muse, mutect2, varscan2
- NKRF | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as rs144370117, COSV58662345; called by muse, mutect2, varscan2
- NTM | c.327C>A p.D109E | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV66177926, COSV66183887; called by muse, mutect2, varscan2
- PADI1 | c.740T>A p.I247N | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.541); catalogued as COSV100969027; called by muse, mutect2, varscan2
- PAXBP1 | c.1730T>C p.I577T | Missense Mutation (SNP) | VAF 67/117 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99269130; called by muse, mutect2, varscan2
- PCSK1 | c.1960C>T p.R654W | Missense Mutation (SNP) | VAF 74/384 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.075); catalogued as rs200614230, COSV60734915; called by muse, mutect2, varscan2
- PDE7B | c.161T>C p.L54P | Missense Mutation (SNP) | VAF 57/258 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV57500967; called by muse, mutect2, varscan2
- PHYHIPL | c.635A>G p.D212G | Missense Mutation (SNP) | VAF 73/141 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99513331; called by muse, mutect2, varscan2
- PLXDC2 | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 88/359 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1460975614, COSV65906348; called by muse, varscan2
- PPARGC1B | c.2605C>T p.R869* | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as rs1313967756, COSV58530637; called by muse, mutect2
- PPP4R3B | c.288A>C p.K96N | Missense Mutation (SNP) | VAF 122/446 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.821); catalogued as COSV99701619; called by muse, mutect2, varscan2
- PREP | c.1142G>A p.G381D (on ENST00000369110; = p.G447D on NM_002726.5) | Missense Mutation (SNP) | VAF 90/332 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.452); catalogued as COSV100963792; called by muse, mutect2, varscan2
- PRKCA | c.1895G>A p.R632Q | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs140466753; called by muse, mutect2, varscan2
- PSRC1 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as rs773919831, COSV100883479; called by muse, mutect2
- RITA1 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs773378868, COSV55322140; called by muse, mutect2, varscan2
- RS1 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.001); catalogued as rs1345077562, COSV66106850; called by muse, mutect2, varscan2
- SCN7A | c.265A>G p.I89V | Missense Mutation (SNP) | VAF 106/210 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV69272701; called by muse, mutect2, varscan2
- SDK2 | c.4424G>A p.R1475Q | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368464336; called by muse, mutect2, varscan2
- SLC16A1 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs774823539, COSV63709858; called by muse, mutect2, varscan2
- SNAPC3 | c.16C>T p.R6* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as rs777523833, COSV66459832; called by muse, mutect2, varscan2
- SPRR3 | c.47T>C p.L16P | Missense Mutation (SNP) | VAF 75/314 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99768462; called by muse, mutect2, varscan2
- SPTA1 | c.7045G>A p.E2349K | Missense Mutation (SNP) | VAF 62/291 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100934612; called by muse, mutect2, varscan2
- SULF2 | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs140812797, COSV63417621; called by muse, mutect2, varscan2
- TBC1D32 | c.888T>A p.N296K | Missense Mutation (SNP) | VAF 56/277 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV51546469; called by muse, mutect2, varscan2
- TENM3 | c.1156G>A p.G386R | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750160895, COSV101304881, COSV69306800; called by muse, mutect2, varscan2
- TMEM130 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs781824607, COSV59557727; called by muse, mutect2, varscan2
- TP53INP2 | c.113T>C p.I38T | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1206623067, COSV100873677; called by muse, mutect2, varscan2
- TTN | c.48424C>G p.L16142V (on ENST00000591111; = p.L8718V on NM_003319.4) | Missense Mutation (SNP) | VAF 121/234 reads (52%) | PolyPhen probably damaging (0.996); catalogued as COSV60153170; called by muse, mutect2, varscan2
- TWIST1 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.121); catalogued as COSV99643007; called by muse, mutect2
- UGT3A2 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 236/732 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.822); catalogued as rs767460678, COSV99236104; called by muse, mutect2, varscan2
- WDR64 | c.1042C>T p.R348W | Missense Mutation (SNP) | VAF 77/163 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751512962, COSV63796893; called by muse, mutect2, varscan2
- XIRP2 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 123/240 reads (51%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.951); catalogued as rs553364503, COSV54711321, COSV54712210, COSV99737765; called by muse, mutect2, varscan2
- FUT11 | c.824_832del p.K275_L278delinsM | In Frame Del (DEL) | VAF 19/82 reads (23%) | called by mutect2, pindel, varscan2
- GGA3 | c.1781-1_1781insTAG p.S594delinsIG (on ENST00000537686 / NM_138619.4; = p.S561delinsIG on NM_014001.5) | Splice Region (INS) | VAF 6/21 reads (29%) | called by mutect2, varscan2
- KRT3 | c.1522_1525dup p.E509Gfs*220 | Frame Shift Ins (INS) | VAF 10/50 reads (20%) | called by pindel, varscan2
- MGAT4A | c.59del p.T20Ifs*15 | Frame Shift Del (DEL) | VAF 70/172 reads (41%) | called by mutect2, pindel, varscan2
- SH2D4A | c.182-3_184del p.X61_splice | Splice Site (DEL) | VAF 37/71 reads (52%) | called by mutect2, pindel, varscan2
- SMAD4 | c.974_975del p.S325Yfs*5 | Frame Shift Del (DEL) | VAF 64/165 reads (39%) | called by mutect2, pindel, varscan2
- ANKRD44 | c.519C>T p.D173= | Silent (SNP) | VAF 55/212 reads (26%) | catalogued as COSV99984452; called by muse, mutect2, varscan2
- CCNJL | c.1143G>A p.P381= | Silent (SNP) | VAF 24/116 reads (21%) | catalogued as rs141268151, COSV57445431; called by muse, mutect2, varscan2
- CRABP1 | c.372C>T p.G124= | Silent (SNP) | VAF 32/127 reads (25%) | catalogued as rs201099878, COSV55115592; called by muse, mutect2, varscan2
- DMD | c.5976A>G p.E1992= | Silent (SNP) | VAF 164/306 reads (54%) | catalogued as COSV63767570; called by muse, varscan2
- DPEP2 | c.1183C>A p.R395= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as COSV99263086; called by muse, mutect2, varscan2
- FAM47C | c.2292G>A p.P764= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as rs1357638692, COSV63723511; called by muse, mutect2, varscan2
- GLP1R | c.456C>T p.Y152= | Silent (SNP) | VAF 62/200 reads (31%) | catalogued as rs200564025, COSV64714685; called by muse, mutect2
- INPP5K | c.201C>T p.A67= | Silent (SNP) | VAF 27/41 reads (66%) | catalogued as COSV100233650; called by muse, mutect2, varscan2
- KIF1A | c.501C>T p.R167= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as rs923432327, COSV57486723; called by muse, mutect2
- MED13 | c.3057G>T p.R1019= | Silent (SNP) | VAF 50/105 reads (48%) | catalogued as COSV101180862; called by muse, mutect2, varscan2
- MGA | c.5970G>A p.T1990= (on ENST00000219905 / NM_001164273.1; = p.T1781= on NM_001080541.2) | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs1391387688, COSV54957025; called by mutect2, varscan2
- MKLN1 | c.1971A>G p.K657= | Silent (SNP) | VAF 126/773 reads (16%) | catalogued as rs775037647, COSV100759751; called by muse, varscan2
- NEK1 | c.3072A>G p.K1024= | Silent (SNP) | VAF 192/341 reads (56%) | catalogued as COSV71456606; called by muse, mutect2, varscan2
- OR5D16 | c.414C>A p.I138= | Silent (SNP) | VAF 112/332 reads (34%) | catalogued as rs747455484, COSV65721333; called by muse, mutect2
- PAQR7 | c.750G>A p.L250= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs758590193, COSV100961637; called by muse, varscan2
- PCYOX1L | c.339C>T p.F113= | Silent (SNP) | VAF 28/170 reads (16%) | catalogued as rs747704482, COSV51002213; called by muse, mutect2, varscan2
- RBPJL | c.1491G>A p.A497= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as COSV100643457; called by muse, varscan2
- ZNF329 | c.1518C>T p.S506= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs763454620, COSV63772815; called by muse, mutect2, varscan2
- CDKN2A | c.150+84C>T | Intron (SNP) | VAF 8/63 reads (13%) | called by muse, mutect2, varscan2
- KNOP1P1 | n.394C>T | RNA (SNP) | VAF 66/83 reads (80%) | catalogued as rs1211563838; called by muse, mutect2, varscan2
- OR5D18 | c.-2C>T | 5'UTR (SNP) | VAF 46/130 reads (35%) | catalogued as rs372961380; called by muse, mutect2, varscan2
- PITPNC1 | c.49-61254C>A | Intron (SNP) | VAF 34/103 reads (33%) | catalogued as rs1253581615, COSV100083089; called by muse, mutect2, varscan2
